Somatic mutation profile of tumor specimen TCGA-G8-6909-01A (aliquot TCGA-G8-6909-01A-11D-2210-10) from TCGA case TCGA-G8-6909, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Intrathoracic lymph nodes; Age at diagnosis: 67.5 years (24,661 days).
Specimen TCGA-G8-6909-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d58a4949-609c-4b73-817b-2a6fa4c842a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G8-6909-14A (Bone Marrow Normal), aliquot TCGA-G8-6909-14A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/515a2c0b-6132-4c99-9a55-4c15635493b2

The open-access MAF lists 392 somatic variants for this specimen: 307 protein-altering or splice-affecting, 82 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 261, Silent 82, Nonsense Mutation 18, Frame Shift Del 11, Splice Site 11, Splice Region 2, Frame Shift Ins 2, In Frame Del 1, RNA 1, 5'Flank 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF8 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs397514711, CM116643, COSV51897805; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB9 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs114398803; called by muse, varscan2
- AFF1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs770921103, COSV100320468; called by muse, mutect2, varscan2
- ANGPTL2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.489); catalogued as rs370920897, COSV52221705; called by muse, mutect2, varscan2
- ANO7 | c.1208G>A p.W403* (on ENST00000274979; = p.W349* on NM_001370694.2) | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as rs750676004, COSV51472243; called by muse, mutect2, varscan2
- ARHGAP21 | c.3043G>A p.D1015N | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767153299, COSV57605096; called by muse, mutect2, varscan2
- ARHGAP45 | c.3365G>A p.R1122Q | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs371515757; called by muse, mutect2, varscan2
- ARID4B | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51608205; called by muse, mutect2, varscan2
- ATR | c.6302C>T p.A2101V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV63393996; called by muse, mutect2, varscan2
- BCKDHB | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as rs769876670; called by muse, mutect2, varscan2
- BCS1L | c.1008G>A p.R336= | Splice Region (SNP) | VAF 38/135 reads (28%) | catalogued as rs1314813758; called by muse, mutect2, varscan2
- BRINP2 | c.741G>T p.L247F | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100837977; called by muse, mutect2, varscan2
- BTG1 | c.201C>G p.Y67* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as COSV55458452, COSV55458671; called by muse, varscan2
- BTG2 | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV51854863; called by muse, mutect2, varscan2
- CAND2 | c.1813C>T p.R605W (on ENST00000456430 / NM_001162499.2; = p.R512W on NM_012298.3) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs367818782; called by muse, mutect2, varscan2
- CCDC180 | c.3483+1G>A p.X1161_splice | Splice Site (SNP) | VAF 16/65 reads (25%) | catalogued as rs376419121; called by muse, mutect2, varscan2
- CCR8 | c.696_698del p.N232del | In Frame Del (DEL) | VAF 76/263 reads (29%) | catalogued as rs769101283; called by pindel, varscan2
- CEP70 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs772317210; called by muse, mutect2, varscan2
- CIC | c.1264C>G p.R422G | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV104381975; called by muse, mutect2, varscan2
- CPN1 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV64942020; called by muse, mutect2, varscan2
- CSNK2A1 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53937543; called by muse, mutect2, varscan2
- CYP4V2 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as rs1344642919, COSV66506869; called by muse, mutect2, varscan2
- DAB1 | c.1642A>G p.S548G (on ENST00000371231; = p.S515G on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs747317225, COSV64690184; called by muse, mutect2, varscan2
- DCLK3 | c.1655C>G p.P552R | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761691293; called by muse, mutect2, varscan2
- DEFB110 | c.106A>T p.R36* | Nonsense Mutation (SNP) | VAF 37/153 reads (24%) | catalogued as COSV64484314; called by muse, mutect2, varscan2
- DIAPH3 | c.2770C>A p.Q924K (on ENST00000400324 / NM_001042517.2; = p.Q661K on NM_030932.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as COSV57380795, COSV99934501; called by muse, mutect2, varscan2
- DIRAS1 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1257475292, COSV100053100; called by muse, mutect2, varscan2
- DOC2A | c.713_714+1del p.X238_splice | Splice Site (DEL) | VAF 33/158 reads (21%) | catalogued as rs1567279283; called by pindel, varscan2
- DOCK4 | c.5291C>G p.T1764S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.026); catalogued as COSV70241354; called by muse, mutect2, varscan2
- DTX1 | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1566011809; called by muse, varscan2
- DUSP2 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.241); catalogued as rs572028879, COSV56619470, COSV56619666; called by muse, varscan2
- FAM102A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs764999375; called by muse, mutect2, varscan2
- FNIP2 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.172); catalogued as rs1249017248; called by muse, mutect2, varscan2
- H1-2 | c.380A>C p.K127T | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs756846037; called by muse, mutect2, varscan2
- H1-3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99768567, COSV99768682; called by muse, mutect2, varscan2
- H1-4 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV104388570; called by muse, mutect2, varscan2
- H2AC17 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); catalogued as rs747129172, COSV58153343, COSV58154128; called by muse, mutect2, varscan2
- H2AC6 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV58415523, COSV58417663; called by muse, mutect2, varscan2
- HLA-A | c.512G>A p.W171* | Nonsense Mutation (SNP) | VAF 42/156 reads (27%) | catalogued as rs199474545, CM1412102, CX1412103; called by muse, mutect2
- HSPA6 | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs1383581949; called by muse, mutect2, varscan2
- IGHE | c.1189T>C p.W397R | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782700638; called by muse, mutect2, varscan2
- IGKC | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as rs188950558; called by muse, mutect2, varscan2
- IGKV1-5 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.257); catalogued as rs191761898; called by muse, mutect2, varscan2
- IGKV1D-8 | c.173A>T p.Y58F | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as rs746427292; called by muse, mutect2, varscan2
- IGKV5-2 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.612); catalogued as rs774400959; called by muse, mutect2, varscan2
- IGLV3-16 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs575435566; called by muse, mutect2, varscan2
- IL5RA | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV56522199; called by muse, mutect2, varscan2
- JAKMIP3 | c.1388C>A p.S463Y | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV53823450; called by muse, mutect2
- JAKMIP3 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs746991217; called by muse, mutect2, varscan2
- JARID2 | c.3130G>A p.A1044T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.632); catalogued as COSV59186154; called by muse, mutect2, varscan2
- KIAA0319 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773814986; called by muse, mutect2, varscan2
- KIF2B | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs776017105, COSV52129130; called by muse, mutect2, varscan2
- KRT73 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs1391846807; called by muse, mutect2, varscan2
- KRTAP4-12 | c.431G>C p.S144T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs536638484; called by muse, mutect2, varscan2
- LCA5L | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs1015753631; called by muse, mutect2, varscan2
- LIMD2 | c.304T>A p.Y102N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1364950392; called by muse, mutect2, varscan2
- LRP1 | c.10771C>T p.R3591C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1319578873; called by muse, mutect2, varscan2
- LRP3 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs368108554; called by muse, mutect2, varscan2
- MAP4K4 | c.107A>T p.Y36F | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs1247613496; called by muse, mutect2, varscan2
- MED24 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772469065, COSV62417912, COSV62419791; called by muse, mutect2, varscan2
- MFSD3 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56742150; called by muse, mutect2, varscan2
- MUC16 | c.38485G>C p.G12829R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.84); catalogued as COSV101200689; called by muse, mutect2, varscan2
- MYH1 | c.4352G>T p.R1451M | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99875557; called by muse, mutect2, varscan2
- NCAN | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377689983; called by muse, mutect2, varscan2
- NEGR1 | c.9G>C p.M3I | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63277080; called by muse, mutect2, varscan2
- NEK11 | c.218C>G p.T73S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV100797581; called by muse, mutect2, varscan2
- NFKBIE | c.759_762del p.Y254Sfs*13 (on ENST00000275015; = p.Y115Sfs*13 on NM_004556.3) | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs755160004; called by mutect2, pindel, varscan2
- OR2T12 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs200352170, COSV58776065, COSV58778849; called by muse, mutect2, varscan2
- OR5H2 | c.698A>T p.K233M | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.142); catalogued as COSV62350912, COSV62350980; called by muse, mutect2
- PAX5 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63911668, COSV63914348; called by muse, mutect2, varscan2
- PCCB | c.694A>T p.K232* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV52445770; called by muse, mutect2, varscan2
- PCDH18 | c.537T>A p.N179K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100787120; called by muse, mutect2, varscan2
- PCNX3 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs538665832, COSV58418959; called by muse, mutect2, varscan2
- PHPT1 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335464090; called by muse, mutect2, varscan2
- PIPOX | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs543013733; called by muse, mutect2, varscan2
- PKHD1 | c.10243C>T p.L3415F | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64397634; called by muse, mutect2, varscan2
- PKHD1 | c.6925G>A p.E2309K | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs754303004, COSV61868202; called by muse, mutect2, varscan2
- PLXNB2 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs375580670; called by muse, varscan2
- PRF1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs151232299; called by muse, mutect2, varscan2
- PSPH | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 120/464 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs761409780; called by muse, mutect2, varscan2
- PTGS1 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs200295924, COSV56294731; called by muse, mutect2, varscan2
- PTHLH | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs769825766; called by muse, mutect2, varscan2
- RBBP8NL | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as rs768351083; called by muse, mutect2, varscan2
- RTEL1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs184051277; called by muse, mutect2, varscan2
- SGK1 | c.77-1G>A p.X26_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as rs186450029, COSV52804758; called by muse, varscan2
- SLC16A3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as rs940545976; called by muse, mutect2, varscan2
- SLC16A7 | c.415T>G p.F139V | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99038887; called by muse, mutect2, varscan2
- SLC8A3 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs776154138; called by muse, mutect2, varscan2
- SOCS1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV59659285, COSV59659496; called by muse, mutect2, varscan2
- STAT6 | c.1263T>A p.N421K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55672341, COSV55674589; called by muse, mutect2, varscan2
- STOX2 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs745749464, COSV57853577; called by muse, mutect2, varscan2
- THNSL1 | c.1853G>A p.W618* | Nonsense Mutation (SNP) | VAF 29/129 reads (22%) | catalogued as rs1247709241; called by muse, mutect2, varscan2
- TRIM11 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs143926476; called by muse, mutect2, varscan2
- TTC39B | c.1106-1G>A p.X369_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99896260; called by muse, mutect2, varscan2
- TUB | c.1210C>T p.R404C (on ENST00000299506 / NM_177972.3; = p.R459C on NM_003320.4) | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs139170512; called by muse, mutect2, varscan2
- ULK2 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1435203618; called by muse, mutect2, varscan2
- UNC5D | c.2797T>C p.S933P | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.796); catalogued as rs1320101565; called by muse, mutect2, varscan2
- USH2A | c.10525A>C p.K3509Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as CM124852; called by muse, mutect2, varscan2
- VIPAS39 | c.1192T>C p.Y398H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.836); catalogued as COSV58938583; called by muse, mutect2, varscan2
- VWA3B | c.3563C>T p.P1188L | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV71372051; called by muse, mutect2, varscan2
- WDR25 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs144754220; called by muse, mutect2, varscan2
- WDR38 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs775409428; called by muse, mutect2, varscan2
- WNK1 | c.4060G>A p.A1354T (on ENST00000315939 / NM_018979.4; = p.A1107T on NM_014823.3) | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV60033233; called by muse, mutect2, varscan2
- WNK3 | c.3715G>A p.G1239S | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as rs1557150940; called by muse, mutect2, varscan2
- ZFHX3 | c.4103A>G p.N1368S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as rs758364697, COSV51737918; called by muse, mutect2, varscan2
- ZFP36L1 | c.57+1G>A p.X19_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as rs563928424, COSV60544075; called by muse, varscan2
- ZNF106 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs201738274; called by muse, mutect2, varscan2
- ZNF345 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100080234; called by muse, mutect2, varscan2
- ZNF568 | c.798del p.T267Hfs*115 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs1236015870; called by mutect2, pindel, varscan2
- ZNF91 | c.3155G>A p.C1052Y | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56087893; called by muse, mutect2, varscan2
- ZSCAN5B | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs750881936, COSV62838346; called by muse, mutect2, varscan2
- AGAP1 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AK9 | c.4849+2T>C p.X1617_splice | Splice Site (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- ANKRD13A | c.159T>A p.H53Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- AOC1 | c.2118del p.S707Pfs*8 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- ARHGAP6 | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF1 | c.2249+1G>A p.X750_splice | Splice Site (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- ASB17 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATG4C | c.553T>A p.Y185N | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP6V0A1 | c.2165T>C p.I722T (on ENST00000343619 / NM_001378531.1; = p.I716T on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRD2 | c.1650_1651del p.K552Rfs*19 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by pindel, varscan2
- BSN | c.6983C>T p.P2328L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- C5 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CAB39L | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CADM2 | c.480C>A p.F160L (on ENST00000407528 / NM_001167674.2; = p.F162L on NM_153184.4) | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CASZ1 | c.3994A>T p.N1332Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAVIN1 | c.476A>C p.E159A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CDH9 | c.1114A>C p.I372L | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CEP164 | c.83-1G>A p.X28_splice | Splice Site (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- CEP290 | c.966T>A p.D322E | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CETN3 | c.134T>G p.I45R | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, varscan2
- CHRM3 | c.104C>G p.T35S | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMYA5 | c.2442A>T p.K814N | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- COL12A1 | c.2380_2389del p.P794Sfs*8 | Frame Shift Del (DEL) | VAF 24/153 reads (16%) | called by mutect2, pindel, varscan2
- CST4 | c.329C>G p.P110R | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DAB2 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DENND4C | c.4016A>G p.N1339S (on ENST00000434457 / NM_001330640.2; = p.N1290S on NM_017925.7) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKH | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- DGLUCY | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DIRAS3 | c.88A>C p.K30Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DNAH5 | c.3142del p.V1048Sfs*45 | Frame Shift Del (DEL) | VAF 22/154 reads (14%) | called by mutect2, pindel, varscan2
- DOCK4 | c.2354A>G p.N785S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DOCK5 | c.2968T>A p.F990I | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DSG3 | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DTX1 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, varscan2
- DUSP2 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ECPAS | c.5476G>T p.E1826* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- EIF4G2 | c.110A>T p.E37V | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- EN1 | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB2 | c.446del p.Q149Rfs*9 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- ERCC2 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2
- F2R | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83B | c.257C>G p.T86S | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FIGN | c.592T>A p.Y198N | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FKBP15 | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- FMNL2 | c.148A>T p.R50W | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FRG2C | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GABRA5 | c.671A>T p.Q224L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GAD1 | c.1659G>C p.M553I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- GBP1 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- GCSAM | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- GGT1 | c.1271T>G p.F424C | Missense Mutation (SNP) | VAF 98/396 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GIGYF2 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- GLRB | c.727T>A p.C243S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GON4L | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPC5 | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- GRIA2 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GTF3C1 | c.3430del p.E1144Rfs*11 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- H1-4 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- H2AZ2 | c.250C>G p.P84A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- H2BC10 | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- H2BC12 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, varscan2
- H4C11 | c.228_232dup p.K78Tfs*? | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, varscan2
- HCN2 | c.1841C>T p.T614I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- HDAC7 | c.1073C>T p.S358L (on ENST00000427332; = p.S397L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HEPH | c.167T>C p.I56T (on ENST00000343002; = p.I110T on NM_138737.5) | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC4 | c.2615G>A p.G872D (on ENST00000395198 / NM_022079.3; = p.G864D on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HERC4 | c.2614G>A p.G872S (on ENST00000395198 / NM_022079.3; = p.G864S on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-A | c.91T>G p.Y31D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- HLA-C | c.483_496del p.T162Hfs*54 | Frame Shift Del (DEL) | VAF 28/123 reads (23%) | called by mutect2, pindel, varscan2
- HLA-DQB1 | c.123C>G p.F41L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXA11 | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HSPA4 | c.742T>C p.F248L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IGHA1 | c.810G>C p.E270D | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- IGHA2 | c.771G>C p.E257D | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- IGHE | c.1090G>T p.V364L | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- IGHE | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHG4 | c.538T>G p.Y180D | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- IGHV1-69 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, varscan2
- IGHV3-35 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | called by muse, varscan2
- IGKV1-8 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- IGKV2-30 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, varscan2
- IGKV4-1 | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2
- IGKV5-2 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.909); called by muse, varscan2
- IGLV4-69 | c.213C>A p.N71K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, varscan2
- KCNK12 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21A | c.3466A>T p.R1156* (on ENST00000361418 / NM_001378440.1; = p.R1143* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- KLB | c.1188A>C p.L396F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL1 | c.1900T>A p.C634S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KLHL32 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- KLHL6 | c.1055A>C p.K352T | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- LACTB | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LCT | c.5500G>A p.V1834M | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- LIMK1 | c.668T>C p.I223T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- LRPPRC | c.1129T>A p.L377I | Missense Mutation (SNP) | VAF 64/544 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.862); called by muse, mutect2
- LRPPRC | c.1127T>G p.F376C | Missense Mutation (SNP) | VAF 63/548 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRIQ1 | c.2452A>C p.T818P | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRK2 | c.2500+1G>A p.X834_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- LRRN3 | c.1768A>G p.K590E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRRTM1 | c.1350G>A p.W450* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- MAGEA4 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MAGI1 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MAGI3 | c.4420A>C p.I1474L | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, varscan2
- MAN1C1 | c.836_850del p.X279_splice | Splice Site (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- MCL1 | c.736T>G p.L246V | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MEGF6 | c.536C>G p.T179S | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MFHAS1 | c.2556C>G p.C852W | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- MFHAS1 | c.1883G>C p.S628T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MOCS1 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSI2 | c.613dup p.Y205Lfs*155 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- MTTP | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC6 | c.1818C>G p.H606Q | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MYBL2 | c.1524G>C p.Q508H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MYO1F | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOZ1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NAGLU | c.2096A>T p.K699I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.361); called by muse, mutect2
- NAGLU | c.2098A>C p.N700H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- NAV3 | c.5650C>A p.L1884I (on ENST00000397909 / NM_001024383.2; = p.L1862I on NM_014903.6) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEUROD6 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- NFIX | c.581C>G p.S194* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-1G>T p.X1122_splice | Splice Site (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- NRXN2 | c.4514T>G p.L1505R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- NUDT12 | c.207G>A p.G69= | Splice Region (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- NUP214 | c.4741G>C p.A1581P | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4D2 | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- P2RY8 | c.635G>A p.C212Y | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC1 | c.1147A>T p.M383L | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PAMR1 | c.1019C>T p.P340L (on ENST00000619888 / NM_001001991.3; = p.P357L on NM_015430.4) | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PANK4 | c.1190G>C p.G397A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPOLA | c.1063A>T p.K355* | Nonsense Mutation (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.1883G>C p.R628P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PDIA4 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PIM1 | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.152); called by muse, varscan2
- PKHD1 | c.3854G>A p.S1285N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POLR3F | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PPP1R16A | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKD1 | c.2217C>A p.F739L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PTPN12 | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRM | c.2710T>A p.Y904N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRU | c.1804G>C p.G602R | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- RAB40B | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- RASSF6 | c.345T>G p.F115L (on ENST00000342081 / NM_201431.2; = p.F83L on NM_177532.5) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBPJL | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ROBO2 | c.1236G>C p.L412F | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- RPTOR | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- RTN3 | c.230C>T p.P77L (on ENST00000377819 / NM_001265589.2; = p.P58L on NM_201428.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SAFB2 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SALL1 | c.1701A>G p.I567M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SAMD8 | c.419A>T p.H140L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SCN9A | c.1281del p.D428Tfs*41 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- SEMA6B | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGK1 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- SLC19A3 | c.596T>G p.F199C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC32A1 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SLC8A1 | c.665T>A p.L222* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLIT2 | c.584T>C p.F195S | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLIT2 | c.807T>A p.S269R | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- SMARCA5 | c.3085A>G p.K1029E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SPATA18 | c.1286C>A p.A429E | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SREBF2 | c.2444T>C p.L815S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SRP72 | c.1880G>T p.R627I | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- STAG2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- STPG4 | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SWAP70 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- TAF1 | c.2755_2757dup p.I919dup (on ENST00000373790 / NM_138923.4; = p.I940dup on NM_004606.5 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 31/106 reads (29%) | called by mutect2, pindel, varscan2
- TAF1L | c.4060G>C p.E1354Q | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- TBATA | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBXA2R | c.695C>G p.A232G | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TECPR1 | c.1934G>T p.S645I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TLE3 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TLN2 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TPX2 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TREX2 | c.833A>C p.E278A (on ENST00000334497; = p.E235A on NM_080701.3) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TRPV1 | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC21A | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TTN | c.42522C>A p.D14174E (on ENST00000591111; = p.D6750E on NM_003319.4) | Missense Mutation (SNP) | VAF 72/259 reads (28%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- U2SURP | c.1425G>A p.W475* | Nonsense Mutation (SNP) | VAF 39/169 reads (23%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.2530G>A p.V844M | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- USH2A | c.12339G>T p.L4113F | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- USP40 | c.1459C>G p.P487A | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- USP43 | c.1769A>G p.K590R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWA3A | c.2028_2030delinsAA p.A678Lfs*44 | Frame Shift Del (DEL) | VAF 33/75 reads (44%) | called by pindel, varscan2*
- WNK1 | c.1253C>A p.S418Y | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WNK1 | c.5462C>A p.A1821E (on ENST00000315939 / NM_018979.4; = p.A1574E on NM_014823.3) | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H4 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZFP36L1 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF142 | c.1321A>G p.M441V (on ENST00000411696 / NM_001379660.1; = p.M241V on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ZNF180 | c.1689C>A p.H563Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ZNF233 | c.89G>T p.R30I | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ZNF285 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- ZNF354C | c.642A>T p.K214N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF426 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF598 | c.2384A>G p.Y795C | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF695 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ZNF804A | c.1748A>T p.K583I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ABO | c.945C>T p.T315= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- AC127029.3 | c.666C>T p.Y222= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs370785603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY4 | c.606G>A p.T202= | Silent (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- ALB | c.1692A>G p.T564= | Silent (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- ANO4 | c.2867G>A p.*956= (on ENST00000392977 / NM_001286615.2; = p.*921= on NM_178826.4) | Silent (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- ATRNL1 | c.2931A>C p.S977= | Silent (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- BPIFB4 | c.408C>T p.L136= | Silent (SNP) | VAF 44/165 reads (27%) | catalogued as rs767891631; called by muse, mutect2, varscan2
- CATSPERB | c.1692C>T p.I564= | Silent (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
- CCDC158 | c.2658G>T p.L886= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- CDC20B | c.762C>T p.Y254= | Silent (SNP) | VAF 58/169 reads (34%) | called by muse, mutect2, varscan2
- CHD8 | c.4464G>A p.V1488= (on ENST00000646647 / NM_001170629.2; = p.V1209= on NM_020920.4) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1369820428; called by muse, mutect2, varscan2
- CMKLR1 | c.168G>A p.L56= (on ENST00000312143 / NM_001142344.2; = p.L54= on NM_004072.3) | Silent (SNP) | VAF 29/112 reads (26%) | called by muse, mutect2, varscan2
- CMYA5 | c.4437T>C p.S1479= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- COL28A1 | c.3219G>A p.L1073= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as rs373840985; called by muse, mutect2, varscan2
- COL9A1 | c.996A>G p.G332= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- CPSF1 | c.1407C>T p.I469= | Silent (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- CR1 | c.96G>A p.V32= | Silent (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- CYP4F3 | c.591C>G p.L197= | Silent (SNP) | VAF 36/127 reads (28%) | called by muse, mutect2
- DGKH | c.3654G>A p.S1218= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs376522940; called by muse, mutect2, varscan2
- DNAH11 | c.12963A>G p.E4321= | Silent (SNP) | VAF 105/186 reads (56%) | called by muse, mutect2, varscan2
- ECD | c.1279C>T p.L427= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1564659887; called by muse, mutect2, varscan2
- ESPN | c.1389A>C p.G463= | Silent (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- FAT3 | c.3246C>T p.I1082= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs746181663; called by muse, mutect2, varscan2
- FGFR2 | c.789G>A p.P263= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs138315382; called by muse, mutect2, varscan2
- FSTL5 | c.687T>A p.A229= | Silent (SNP) | VAF 50/196 reads (26%) | called by muse, mutect2, varscan2
- GJA8 | c.378G>A p.Q126= | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- GPR149 | c.69G>A p.T23= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as rs777546936, COSV101078479; called by muse, mutect2, varscan2
- GPR161 | c.1554C>T p.I518= | Silent (SNP) | VAF 48/180 reads (27%) | catalogued as rs757739221, COSV99606296; called by muse, mutect2, varscan2
- GRIA1 | c.1401A>C p.R467= | Silent (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- GRIP2 | c.2883C>T p.A961= (on ENST00000619221; = p.A864= on NM_001080423.4) | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs1013557189; called by muse, mutect2, varscan2
- H2AC6 | c.345G>A p.V115= | Silent (SNP) | VAF 36/117 reads (31%) | called by muse, mutect2, varscan2
- HSPG2 | c.504C>T p.V168= | Silent (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.117G>C p.L39= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as rs759053296; called by muse, varscan2
- IGHV3-35 | c.201A>C p.V67= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- IGKV2-30 | c.208A>C p.R70= | Silent (SNP) | VAF 78/346 reads (23%) | catalogued as rs770004479; called by muse, varscan2
- IGKV2-30 | c.60G>A p.G20= | Silent (SNP) | VAF 62/311 reads (20%) | called by muse, varscan2
- IWS1 | c.2241A>G p.G747= | Silent (SNP) | VAF 26/126 reads (21%) | called by muse, varscan2
- KCND1 | c.189C>T p.D63= | Silent (SNP) | VAF 48/152 reads (32%) | called by muse, mutect2, varscan2
- KLHL13 | c.1380T>C p.C460= | Silent (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
- LAMA1 | c.5400A>G p.Q1800= | Silent (SNP) | VAF 52/190 reads (27%) | called by muse, mutect2, varscan2
- LRP1 | c.1446G>A p.Q482= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1184453834; called by muse, mutect2
- LRRC15 | c.1599C>T p.T533= | Silent (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- LTB | c.252C>T p.S84= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs4647186, COSV65815060; called by muse, mutect2, varscan2
- MACROH2A1 | c.1029C>G p.S343= (on ENST00000510038; = p.S342= on NM_004893.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/214 reads (29%) | catalogued as rs1466793588; called by muse, mutect2, varscan2
- MFHAS1 | c.2421T>G p.L807= | Silent (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- MFHAS1 | c.1251T>C p.H417= | Silent (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- MMS19 | c.2970G>A p.L990= | Silent (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- MRTFA | c.375T>C p.Y125= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as rs1218535685; called by muse, mutect2
- MSRB3 | c.555C>T p.A185= | Silent (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- MTSS1 | c.1392G>A p.S464= | Silent (SNP) | VAF 64/123 reads (52%) | catalogued as rs145509745; called by muse, mutect2, varscan2
- MUC16 | c.40800C>T p.S13600= | Silent (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- NRXN1 | c.1545C>T p.G515= | Silent (SNP) | VAF 51/241 reads (21%) | catalogued as rs745993564, COSV58444668; called by muse, mutect2, varscan2
- NUP188 | c.2622G>A p.L874= | Silent (SNP) | VAF 37/173 reads (21%) | called by muse, mutect2, varscan2
- OR13C3 | c.825G>T p.L275= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- OR8J1 | c.309G>C p.G103= | Silent (SNP) | VAF 46/181 reads (25%) | catalogued as COSV57317863; called by muse, mutect2, varscan2
- PCDHB8 | c.1533C>T p.N511= | Silent (SNP) | VAF 48/374 reads (13%) | catalogued as rs1554281276, COSV50754049; called by muse, mutect2, varscan2
- PFKM | c.735C>T p.R245= | Silent (SNP) | VAF 45/193 reads (23%) | called by muse, mutect2, varscan2
- PFKP | c.2196G>A p.V732= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs775141399; called by muse, mutect2, varscan2
- PIM1 | c.468G>T p.R156= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV100998683, COSV65166579; called by muse, mutect2, varscan2
- PKDREJ | c.1326G>A p.A442= | Silent (SNP) | VAF 45/167 reads (27%) | catalogued as rs772195312; called by muse, mutect2, varscan2
- PPP1R21 | c.537A>C p.L179= | Silent (SNP) | VAF 31/311 reads (10%) | called by muse, mutect2, varscan2
- RAD54B | c.384T>C p.V128= | Silent (SNP) | VAF 101/216 reads (47%) | called by muse, mutect2, varscan2
- SLITRK1 | c.429A>G p.R143= | Silent (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- SOX12 | c.822G>A p.P274= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- SPATA16 | c.309T>G p.L103= | Silent (SNP) | VAF 38/160 reads (24%) | called by muse, mutect2, varscan2
- TAGAP | c.864T>C p.T288= | Silent (SNP) | VAF 32/105 reads (30%) | called by muse, varscan2
- TASOR2 | c.7089A>C p.R2363= | Silent (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- TFPI2 | c.495A>C p.G165= | Silent (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- TG | c.5724G>A p.E1908= | Silent (SNP) | VAF 40/71 reads (56%) | catalogued as COSV99600250, COSV99600577; called by muse, mutect2, varscan2
- TMEM151A | c.297G>A p.L99= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as rs1337717570; called by muse, mutect2, varscan2
- UFC1 | c.114C>G p.S38= | Silent (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- USP48 | c.2151G>A p.K717= | Silent (SNP) | VAF 57/181 reads (31%) | catalogued as COSV57610966; called by muse, mutect2, varscan2
- UTP20 | c.78T>G p.V26= | Silent (SNP) | VAF 26/97 reads (27%) | called by muse, varscan2
- WDR90 | c.2730G>A p.V910= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs369151964; called by muse, mutect2, varscan2
- XDH | c.2472G>A p.V824= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as COSV101052118; called by muse, mutect2, varscan2
- ZBBX | c.813C>T p.T271= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs375095384; called by muse, mutect2, varscan2
- ZBP1 | c.489G>A p.T163= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs992460034, COSV59061884, COSV59062404; called by muse, mutect2
- ZBTB6 | c.1083G>A p.K361= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as rs1344401219; called by muse, mutect2, varscan2
- ZC3HC1 | c.822A>G p.Q274= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs753453058; called by muse, mutect2, varscan2
- ZNF460 | c.207C>T p.A69= | Silent (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- ZNF804A | c.645T>C p.S215= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV56451180, COSV56458592; called by muse, mutect2, varscan2
- ZNF883 | c.195A>G p.G65= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- COL4A5 | c.3791-2750C>A | Intron (SNP) | VAF 46/67 reads (69%) | called by muse, mutect2, varscan2
- LINC00518 | n.729A>T | RNA (SNP) | VAF 49/126 reads (39%) | called by muse, mutect2, varscan2
- RAPGEF5 | chr7:22194017 G>A | 5'Flank (SNP) | VAF 11/70 reads (16%) | catalogued as rs375862364; called by muse, mutect2, varscan2
